Somatic mutation profile of tumor specimen TCGA-DU-A7TC-01A (aliquot TCGA-DU-A7TC-01A-21D-A34J-08) from TCGA case TCGA-DU-A7TC, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.5 years (11,884 days).
Specimen TCGA-DU-A7TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 370ed4cb-667b-4ee9-898d-34e342c4155d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TC-10A (Blood Derived Normal), aliquot TCGA-DU-A7TC-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e7fb8c4-b5d2-4bd3-8e8b-d0f61429ac62

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Splice Site 2, In Frame Del 2, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs764217842, COSV99976002; called by muse, mutect2, varscan2
- ADAM32 | c.2206A>G p.S736G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101165413; called by muse, mutect2, varscan2
- ARHGAP31 | c.947A>G p.D316G | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99957216; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2
- FCGR2C | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV100912873; called by muse, varscan2
- KIT | c.1685A>G p.E562G | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.053); catalogued as COSV55391536, COSV99854448; called by muse, mutect2, varscan2
- OBSCN | c.10190G>A p.R3397H | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs559670799, COSV52765980; called by muse, mutect2, varscan2
- PAK2 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59083006; called by muse, mutect2, varscan2
- R3HDM1 | c.698+2T>A p.X233_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | catalogued as COSV99926322; called by muse, mutect2, varscan2
- SRRT | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs775471328, COSV53820665; called by muse, mutect2, varscan2
- SSTR3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs773577020, COSV100142693; called by muse, mutect2, varscan2
- SYNE1 | c.17605A>G p.T5869A (on ENST00000367255 / NM_182961.4; = p.T5798A on NM_033071.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV99567161; called by muse, mutect2, varscan2
- TFCP2L1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV55290037; called by muse, mutect2, varscan2
- ANGPTL5 | c.1157_1159del p.Y386del | In Frame Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- AXIN2 | c.1644del p.E548Dfs*141 | Frame Shift Del (DEL) | VAF 51/152 reads (34%) | called by mutect2, pindel, varscan2
- BZW2 | c.1109-1G>T p.X370_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ETFB | c.430del p.W144Gfs*10 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- TTBK2 | c.3484_3492del p.R1162_S1164del | In Frame Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- COL1A1 | c.3174C>T p.G1058= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- COL7A1 | c.4350T>C p.S1450= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100096517; called by muse, mutect2, varscan2
- KRT2 | c.492C>T p.N164= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs201708557, COSV59012212; called by muse, varscan2
- LRP6 | c.3582A>G p.V1194= | Silent (SNP) | VAF 97/216 reads (45%) | catalogued as COSV99743490; called by muse, mutect2, varscan2
- TRRAP | c.8436T>A p.A2812= (on ENST00000359863 / NM_001244580.1; = p.A2794= on NM_003496.3) | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100722579; called by muse, mutect2, varscan2
- TTN | c.79506T>A p.S26502= (on ENST00000591111; = p.S19078= on NM_003319.4) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100616721; called by muse, mutect2, varscan2
- KIR3DX1 | n.616C>A | RNA (SNP) | VAF 10/111 reads (9%) | catalogued as COSV99683281, COSV99683387; called by muse, mutect2
- THSD4 | c.1016-70072G>C | Intron (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
